TCGA case TCGA-CJ-4891 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d232f22d-a3e7-41c8-97e1-205de2b488aa

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 819 days (2.2 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 57.7 years (21,059 days); Year of diagnosis: 2005; AJCC staging edition: 7th; AJCC pathologic T: T3c; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G4; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5.
2. Hodgkin lymphoma, NOS: ICD-O-3 morphology code: 9650/3; Tissue or organ of origin: Lymph node, NOS; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 819 days (2.2 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets: Elevated.
- Lactate Dehydrogenase: Normal.
- Hemoglobin: Low.
- Leukocytes: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3.2; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-CJ-4891-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15.
  Slide TCGA-CJ-4891-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-CJ-4891-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4891-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 3.4; Intermediate dimension: 0.9; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Follow-up form: New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lymph node(s); Other malignancy histological type: Hodkin's lymphoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 819 days; disease-specific survival: no event (censored), 819 days; progression-free interval: no event (censored), 819 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-CJ-4891-01): tumor purity 0.24, ploidy 1.91, whole-genome doublings 0 (call status: legacy_call).
